Surgical pathology report (de-identified scan), TCGA case TCGA-3H-AB3M, project TCGA-MESO (Mesothelioma), tissue source site MD Anderson Cancer Center, specimen TCGA-3H-AB3M-01A (Primary Tumor).

Accession: [REDACTED]
Specimen Date/Time:

ICD-O-3
Mesothelioma, epithelioid,
malignant 9052/3
Site: @ Penna NOS C38.4
6/13/14

DIAGNOSIS

- (A) PLEURAL BIOPSY:
MALIGNANT EPITHELIOID MESOTHELIOMA (SEE COMMENT)

COMMENT:

Immunohistochemical studies done on tumor sections show strong positive staining for WT-1, mesothelin and keratin 5/6 and negative staining for MOC-31 in the neoplastic cells. The immunohistochemical patterns supports the above diagnosis..

GROSS DESCRIPTION

- (A) PLEURAL BIOPSY - Two pieces of tan-white tissue (0.2 x 0.2 x 0.2 and 1.2 x 0.5 x 0.3 cm). The smallest piece and half of the larger piece are submitted for frozen section. The remaining tissue is submitted for permanent.

SECTION CODE: A1, frozen section (three pieces of tissue); A2, remaining pleural biopsy.

*FS/DX: MALIGNANT NEOPLASM CONSISTENT WITH HISTORY OF MALIGNANT MESOTHELIOMA.

Dx ed elsewhere - staging + surgery @ TSS facility.

CLINICAL HISTORY

Left pleural mesothelioma.

SNOMED CODES

T-29000, M-90503

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file a30be75d-8520-4423-862d-b35aa37e2e39 (TCGA-3H-AB3M.3D2B553B-192D-4300-AF57-781143D0F10B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).